Somatic mutation profile of tumor specimen TCGA-BR-8683-01A (aliquot TCGA-BR-8683-01A-11D-2394-08) from TCGA case TCGA-BR-8683, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 75.4 years (27,549 days).
Specimen TCGA-BR-8683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06d19120-8932-4bda-b398-ff6f88103124.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8683-10A (Blood Derived Normal), aliquot TCGA-BR-8683-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63e6881b-6f83-4377-aa27-961fdbca3ed1

The open-access MAF lists 155 somatic variants for this specimen: 113 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 37, Nonsense Mutation 8, Splice Site 2, Frame Shift Ins 2, In Frame Del 2, Frame Shift Del 2, RNA 2, 3'UTR 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.362G>C p.C121S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1057519731, COSV61069878; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTCH1 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 30/123 reads (24%) | catalogued as rs863224650, CM066203, COSV59462369, COSV59487305; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SRD5A2 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs121434248, CM920642, COSV51871052; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.675del p.G226Afs*21 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs1567550076, COSV52891821; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADGRD1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs144030317; called by muse, mutect2, varscan2
- AGTPBP1 | c.2515G>T p.D839Y (on ENST00000357081 / NM_001330701.2; = p.D799Y on NM_015239.2) | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61270180; called by muse, mutect2, varscan2
- ALG3 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.612); catalogued as COSV56610860; called by muse, mutect2, varscan2
- ANKRD50 | c.3441G>C p.Q1147H | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV72385338; called by muse, mutect2, varscan2
- ARAP1 | c.1078T>G p.F360V (on ENST00000393609 / NM_001040118.2; = p.F115V on NM_015242.4) | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100501614; called by muse, mutect2
- ARVCF | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54265919; called by muse, mutect2, varscan2
- B4GALNT1 | c.955C>A p.R319S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs144725094, COSV57545534; called by muse, mutect2, varscan2
- BCAS2 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.312); catalogued as COSV65767370; called by muse, mutect2, varscan2
- CALCRL | c.764A>T p.Y255F | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV66474206; called by muse, mutect2
- CCAR1 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56268573; called by muse, mutect2, varscan2
- CCDC78 | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV52401554; called by muse, mutect2, varscan2
- CFHR3 | c.17A>G p.N6S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.441); catalogued as COSV66401867; called by muse, mutect2, varscan2
- CHGB | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66760043; called by muse, mutect2, varscan2
- CHGB | c.1996C>G p.L666V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100972924; called by muse, varscan2
- CHST6 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1041148351, COSV59999831; called by muse, mutect2, varscan2
- COL20A1 | c.3314G>A p.G1105E | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58914457; called by muse, mutect2
- CPB1 | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV51572404; called by muse, mutect2, varscan2
- CREB3L2 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs747151734, COSV57792489; called by muse, mutect2, varscan2
- CXXC5 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.823); catalogued as COSV56793274; called by muse, mutect2, varscan2
- CYP4F22 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs745666110, COSV54107542; called by muse, mutect2, varscan2
- DDX28 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs570050909, COSV60105711; called by muse, mutect2, varscan2
- DLGAP1 | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV59795347; called by muse, mutect2, varscan2
- DNAH11 | c.2299G>T p.V767L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV60948866; called by muse, mutect2, varscan2
- DNAJC13 | c.6206C>T p.A2069V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV53448186; called by muse, mutect2, varscan2
- DUOX1 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs767305748, COSV58479095; called by muse, mutect2, varscan2
- EGLN2 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV58279621; called by muse, mutect2, varscan2
- EHBP1 | c.636A>T p.E212D | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as rs1450357004, COSV50417921; called by muse, mutect2, varscan2
- ELAPOR2 | c.1735A>T p.R579* (on ENST00000450689 / NM_001142749.3; = p.R412* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV51885433; called by muse, mutect2
- F13B | c.1721C>T p.T574I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV66373079; called by muse, mutect2, varscan2
- FBF1 | c.1897A>T p.I633F (on ENST00000586717; = p.I647F on NM_001319193.1) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV59864187; called by muse, mutect2, varscan2
- GAS2L1 | c.1732G>T p.G578C | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV53330231; called by muse, mutect2, varscan2
- GHSR | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV53838162; called by muse, mutect2, varscan2
- GLI3 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.379); catalogued as COSV67886973; called by muse, mutect2, varscan2
- GPR137B | c.241T>A p.F81I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63990823; called by muse, mutect2, varscan2
- HCN1 | c.1984A>G p.T662A | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.024); catalogued as COSV57502069; called by muse, mutect2, varscan2
- HIGD1A | c.161C>A p.T54N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV58414782; called by muse, mutect2, varscan2
- IGSF10 | c.6953A>G p.E2318G | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV56373936; called by muse, mutect2
- IL17B | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs377701351; called by muse, mutect2, varscan2
- IRAG2 | c.3649G>A p.V1217I (on ENST00000636465; = p.V262I on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199993006, COSV63138156; called by muse, mutect2, varscan2
- ITIH2 | c.1346T>A p.F449Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.959); catalogued as COSV64432599; called by muse, mutect2, varscan2
- KATNIP | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1286736049, COSV55176926; called by muse, mutect2, varscan2
- KCNT2 | c.3068G>C p.R1023T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV54072683; called by muse, mutect2, varscan2
- KHDC4 | c.655A>G p.S219G | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV64164795; called by muse, mutect2, varscan2
- KIAA1109 | c.12205A>T p.K4069* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV52667392; called by muse, mutect2, varscan2
- KIF14 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs371788866; called by muse, mutect2, varscan2
- KIF6 | c.1704C>A p.D568E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54672538; called by muse, mutect2, varscan2
- KIT | c.1315G>C p.D439H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV55394971; called by muse, mutect2, varscan2
- KRTAP1-5 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs201736812; called by muse, mutect2, varscan2
- LILRB5 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60256082; called by muse, mutect2, varscan2
- LRP1B | c.1165C>A p.L389I | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV67202085; called by muse, mutect2, varscan2
- LRRC30 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 97/181 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67301533; called by muse, mutect2, varscan2
- LRRN2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141763834; called by muse, mutect2, varscan2
- MMP11 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs776950374, COSV53155854; called by muse, mutect2, varscan2
- MS4A8 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV55753703; called by muse, mutect2, varscan2
- NOS1 | c.4043G>A p.G1348E | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.351); catalogued as rs781077618, COSV57609674; called by muse, mutect2, varscan2
- NRDC | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 16/81 reads (20%) | catalogued as COSV61403260; called by muse, mutect2, varscan2
- OR10S1 | c.686T>G p.V229G | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV73342720; called by muse, mutect2, varscan2
- OR1L1 | c.645G>T p.Q215H (on ENST00000373686; = p.Q165H on NM_001005236.3) | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV58935441; called by muse, mutect2
- OR2AT4 | c.408C>A p.H136Q | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as COSV59406725; called by muse, mutect2, varscan2
- PAX3 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs142651003, COSV60589590; called by muse, mutect2, varscan2
- PCDH15 | c.2220A>T p.K740N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV57285272; called by muse, mutect2, varscan2
- PCDH18 | c.1135G>T p.V379F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61267371; called by muse, mutect2, varscan2
- PCDHB1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1554267169, COSV60630142; called by muse, mutect2, varscan2
- PCDHB3 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.026); catalogued as COSV50567547; called by muse, mutect2, varscan2
- PCDHB5 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.048); catalogued as rs1251535727, COSV50647140; called by muse, mutect2, varscan2
- PCDHGA2 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV53920803; called by muse, mutect2, varscan2
- PDE5A | c.1905+2T>G p.X635_splice | Splice Site (SNP) | VAF 14/103 reads (14%) | catalogued as COSV53346786; called by muse, mutect2, varscan2
- PEX11A | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765242326, COSV55583218; called by muse, mutect2
- PPP1R12B | c.2267C>T p.S756L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51782499; called by muse, mutect2, varscan2
- PTPRK | c.2440G>T p.E814* (on ENST00000368215 / NM_001291984.2; = p.E815* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100950471, COSV63908372; called by mutect2, varscan2
- RAG1 | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV55024553; called by muse, mutect2, varscan2
- RETREG1 | c.921C>G p.D307E (on ENST00000306320 / NM_001034850.2; = p.D166E on NM_019000.4) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.251); catalogued as COSV60447554; called by muse, mutect2, varscan2
- RRP1B | c.661G>C p.V221L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV61478596, COSV61478740; called by muse, mutect2, varscan2
- RXRG | c.379C>G p.P127A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV63231755; called by muse, mutect2, varscan2
- RXRG | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV63231759, COSV63231893; called by muse, mutect2, varscan2
- RYR2 | c.8798T>A p.V2933E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV63675769; called by muse, mutect2, varscan2
- SERPINA1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs199422208, CM012639, COSV63345470; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- SF3A2 | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV55554015; called by muse, mutect2, varscan2
- SGK2 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as rs1418576840, COSV58312672; called by muse, mutect2, varscan2
- SI | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52272025; called by muse, mutect2, varscan2
- SLITRK6 | c.2159G>A p.S720N | Missense Mutation (SNP) | VAF 57/396 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV104434466, COSV68389804; called by muse, mutect2, varscan2
- STON2 | c.1716A>C p.K572N (on ENST00000649389 / NM_001366849.2; = p.K515N on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV50843295; called by muse, mutect2, varscan2
- SYNE2 | c.11701T>G p.S3901A | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV59945249; called by muse, mutect2, varscan2
- SYT11 | c.947G>T p.R316I | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV64173939; called by muse, mutect2, varscan2
- TAF6 | c.397+2T>C p.X133_splice | Splice Site (SNP) | VAF 30/87 reads (34%) | catalogued as COSV59841097; called by muse, mutect2, varscan2
- TBCB | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs1437377322, COSV55692110; called by muse, mutect2, varscan2
- TENT4A | c.2024G>A p.R675K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV50094897; called by muse, mutect2, varscan2
- TMEM132B | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54749590; called by muse, mutect2, varscan2
- TMEM225 | c.541T>C p.C181R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.038); catalogued as COSV66693007; called by muse, mutect2, varscan2
- TNFRSF11A | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54022655; called by muse, mutect2, varscan2
- TNFRSF11B | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 17/165 reads (10%) | catalogued as COSV52070131; called by muse, mutect2, varscan2
- TTN | c.94511G>T p.R31504L (on ENST00000591111; = p.R24080L on NM_003319.4) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | PolyPhen probably damaging (0.995); catalogued as COSV59967109; called by muse, mutect2, varscan2
- TTN | c.58369G>C p.G19457R (on ENST00000591111; = p.G12033R on NM_003319.4) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | PolyPhen probably damaging (0.967); catalogued as COSV59967138, COSV60276002; called by muse, mutect2, varscan2
- TTN | c.41897C>A p.P13966H (on ENST00000591111; = p.P6542H on NM_003319.4) | Missense Mutation (SNP) | VAF 4/49 reads (8%) | PolyPhen benign (0.318); catalogued as COSV59967176; called by muse, mutect2
- UBASH3A | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52311497; called by muse, mutect2, varscan2
- UNC80 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.084); catalogued as rs769494103, COSV55893767; called by muse, mutect2, varscan2
- USP34 | c.5504G>T p.C1835F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV68399229, COSV68399830; called by muse, mutect2, varscan2
- USP49 | c.1517C>A p.T506K | Missense Mutation (SNP) | VAF 233/377 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV51895784; called by muse, mutect2, varscan2
- VENTX | c.350G>T p.S117I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV58084316; called by muse, mutect2, varscan2
- WDR90 | c.3652G>T p.D1218Y | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53467995; called by muse, mutect2, varscan2
- ZNF417 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 30/222 reads (14%) | catalogued as rs149986649; called by muse, mutect2, varscan2
- ZNF626 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV74128873; called by muse, mutect2, varscan2
- ACACA | c.65dup p.T23Dfs*18 | Frame Shift Ins (INS) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- ACTR10 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- CCSER1 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- IGHE | c.10_11del p.Q4Efs*166 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2
- KMT2E | c.691dup p.S231Kfs*12 | Frame Shift Ins (INS) | VAF 12/80 reads (15%) | called by mutect2, varscan2
- LRRC24 | c.463_465del p.E155del | In Frame Del (DEL) | VAF 14/73 reads (19%) | called by mutect2, pindel, varscan2
- UBR5 | c.2107_2109del p.S703del | In Frame Del (DEL) | VAF 19/62 reads (31%) | called by pindel, varscan2
- AL592490.1 | c.1086A>G p.K362= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV69425461, COSV69425526; called by muse, mutect2, varscan2
- BTBD9 | c.378G>A p.E126= | Silent (SNP) | VAF 47/393 reads (12%) | catalogued as COSV58423030; called by muse, mutect2, varscan2
- C11orf94 | c.261C>G p.P87= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV53797269; called by muse, mutect2, varscan2
- C1GALT1 | c.981T>G p.R327= | Silent (SNP) | VAF 35/171 reads (20%) | catalogued as COSV56179098; called by muse, mutect2, varscan2
- CACTIN | c.486G>A p.T162= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs766510486, COSV50267401; called by muse, mutect2, varscan2
- CFAP65 | c.4095C>A p.G1365= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV58559359; called by muse, mutect2, varscan2
- CHRNA2 | c.1089C>T p.P363= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV53557013; called by muse, mutect2, varscan2
- COX10 | c.285A>G p.E95= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV55403974; called by muse, mutect2, varscan2
- FAM81B | c.600C>T p.H200= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs373840204; called by muse, mutect2, varscan2
- GBF1 | c.4314C>T p.G1438= (on ENST00000369983 / NM_001377137.1; = p.G1437= on NM_004193.3) | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV64143911; called by muse, mutect2, varscan2
- HNRNPM | c.723A>C p.G241= | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as COSV57692040, COSV57692109; called by muse, mutect2, varscan2
- KCNS2 | c.1191A>G p.A397= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV54637913; called by muse, mutect2, varscan2
- KIF20A | c.2214G>A p.Q738= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs1048564794, COSV67509602; called by muse, mutect2, varscan2
- KIFC1 | c.1194C>T p.A398= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as COSV65737426; called by muse, mutect2, varscan2
- LRFN1 | c.543G>A p.A181= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs370441483; called by muse, mutect2, varscan2
- MFSD2B | c.615C>T p.G205= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs563738803, COSV57854322; called by muse, mutect2
- MRPL3 | c.999T>C p.Y333= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV53913902; called by muse, mutect2
- MVP | c.1443C>A p.V481= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV62421707; called by muse, mutect2, varscan2
- MYH13 | c.4077C>T p.A1359= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as rs1453309267, COSV52823995, COSV52838086; called by muse, mutect2, varscan2
- NEFM | c.609C>T p.I203= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV55331404; called by muse, mutect2, varscan2
- OAS2 | c.237C>T p.L79= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as rs368181112; called by muse, mutect2, varscan2
- P2RY10 | c.267C>T p.L89= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as COSV50680744; called by muse, mutect2, varscan2
- PCDHA9 | c.1980G>A p.T660= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs372827076, COSV65324965, COSV65332396; called by muse, mutect2, varscan2
- PCDHGB7 | c.1506G>A p.S502= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as COSV53922315; called by muse, mutect2, varscan2
- PGBD1 | c.2421G>A p.L807= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV52552327; called by muse, mutect2
- PHRF1 | c.3045A>G p.G1015= (on ENST00000264555 / NM_001286581.2; = p.G1014= on NM_020901.4) | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV52753530; called by muse, mutect2, varscan2
- POLR1B | c.1677C>T p.D559= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs189967507, COSV54494905; called by muse, mutect2, varscan2
- RUNX2 | c.606C>T p.T202= | Silent (SNP) | VAF 23/299 reads (8%) | catalogued as rs776247579, COSV61839846; called by muse, mutect2
- SALL2 | c.2424A>G p.A808= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV58102614; called by muse, mutect2, varscan2
- SGCA | c.1077C>T p.T359= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV56248827; called by muse, mutect2, varscan2
- SHCBP1L | c.1506A>T p.I502= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as COSV62354236; called by muse, mutect2, varscan2
- SLC17A4 | c.1164C>T p.V388= | Silent (SNP) | VAF 7/176 reads (4%) | called by muse, mutect2
- SNTN | c.195G>A p.L65= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as COSV59538728; called by muse, mutect2, varscan2
- UBR5 | c.5319C>T p.N1773= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs985463547, COSV55281441; called by muse, mutect2, varscan2
- VGLL3 | c.267C>A p.V89= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV67352730; called by muse, varscan2
- XPC | c.1242G>A p.Q414= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as rs1386347779, COSV53204266; called by muse, mutect2, varscan2
- ZNF429 | c.1188C>T p.P396= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs759709578, COSV100641759, COSV61915433; called by muse, mutect2, varscan2
- HLA-F | chr6:29726995 C>T | 3'Flank (SNP) | VAF 21/187 reads (11%) | catalogued as COSV52575004; called by muse, mutect2, varscan2
- KIR3DX1 | n.62_66dup | RNA (INS) | VAF 7/71 reads (10%) | called by mutect2, pindel, varscan2
- NACA | c.71-1537C>T | Intron (SNP) | VAF 11/59 reads (19%) | catalogued as rs368947398; called by muse, mutect2, varscan2
- SNORD116-9 | n.83G>A | RNA (SNP) | VAF 23/172 reads (13%) | catalogued as rs750310563; called by muse, mutect2, varscan2
- TAFA3 | c.*14C>T | 3'UTR (SNP) | VAF 20/53 reads (38%) | catalogued as rs111766819; called by muse, mutect2, varscan2
